Gene-level copy-number profile of tumor specimen TCGA-A6-6653-01A from TCGA case TCGA-A6-6653, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 82.1 years (29,996 days).
Specimen TCGA-A6-6653-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ef7b93ff-5eaf-430d-992c-05e161fab12d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6653-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42868c09-d076-4dc5-b777-9b2407b3d0de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 3,210; copy number 2: 56,578.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6653-01A-11D-1770-01): tumor purity 0.81, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:202,505,012–202,769,757, 11 genes: H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B.
- chr2:202,773,720–202,774,360, 1 gene: AC098831.1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr16:6,703,883–7,126,639, 6 genes: AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1.
- chr16:78,793,584–78,796,362, 1 gene: AC009141.1.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:39,597,147–39,612,910, 1 gene: B3GALT5-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
